Gene-level copy-number profile of tumor specimen ALCH-AC5N-TTP1-A from ALCHEMIST case ALCH-AC5N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,604 days).
Specimen ALCH-AC5N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7dd8fe71-0093-4209-a3b7-ca587ee41f67.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AC5N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/e3fe6480-00e2-4fb8-8424-389bcd5eb363

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 204; copy number 1: 3,120; copy number 2: 54,058; copy number 3: 1,523; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,466,937–41,484,683, 2 genes: RNA5SP45, EDN2.
- chr1:54,980,628–54,992,288, 2 genes: TMEM61, AL590440.1.
- chr5:176,203,314–176,203,710, 1 gene: AC139493.1.
- chr8:140,572,142–140,572,812, 1 gene (within-gene range 0–1): AC067931.1.
- chr11:118,702,342–118,702,447, 1 gene: RNU6-376P.
- chr12:34,190,471–34,249,958, 4 genes: AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr17:16,922,915–16,972,118, 2 genes: TBC1D27P, TNFRSF13B.
- chr17:77,442,109–77,472,770, 4 genes (within-gene range 0–2): Y_RNA, AC111170.3, AC111170.2, AC111170.1.
- chr19:4,641,374–4,670,362, 2 genes (within-gene range 0–2): MYDGF, AC005339.1.
- chr19:39,480,412–39,493,785, 1 gene: TIMM50.
- chr20:10,637,684–10,673,999, 2 genes (within-gene range 0–2): JAG1, MIR6870.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 7: AC113430.1.

Autosomal genes at a single copy (total copy number 1): 527. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
